TARGET case TARGET-30-PAPCSJ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/f3517a34-6d95-5221-ba9b-3fc3177df6b3

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.9 years (1,430 days); Year of diagnosis: 2005; Days to last follow up: 376 days (1.0 years); INSS stage: Stage 4.
